Somatic mutation profile of tumor specimen 0DQHB5 from CCDI case PBCEPM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of abdomen; Age at diagnosis: 15.6 years (5,707 days).
Specimen 0DQHB5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94628126-a010-4257-98dd-af98411920dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQHAD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8d0a05e4-b660-413e-bf6d-a74eb8d7d823

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 4, Silent 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11B1 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 188/1267 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs370188543; called by muse, mutect2, varscan2
- POMGNT1 | c.950+7C>G | Splice Region (SNP) | VAF 68/972 reads (7%) | catalogued as COSV100915420; called by muse, mutect2
- CSMD3 | c.5846C>T p.T1949I (on ENST00000297405 / NM_001363185.1; = p.T1845I on NM_052900.3) | Missense Mutation (SNP) | VAF 80/2116 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2
- INAVA | c.1062G>T p.Q354H | Missense Mutation (SNP) | VAF 543/1201 reads (45%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZC2HC1C | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 234/552 reads (42%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- CALN1 | c.564C>T p.C188= (on ENST00000329008 / NM_001017440.3; = p.C230= on NM_031468.4) | Silent (SNP) | VAF 689/1606 reads (43%) | catalogued as rs1262253638, COSV61135658; called by muse, mutect2, varscan2
- MIA2 | c.57A>G p.L19= | Silent (SNP) | VAF 240/578 reads (42%) | catalogued as rs747215161; called by muse, mutect2, varscan2
